Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27L, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27L-01A (Primary Tumor).

1CD-0-3
Carcinoma, infiltrating duct, NOS 8506/3
Site: breast, NOS C50.9 hr 5/19/11

page 1 / 1

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Value of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XX

Age:

Gender: F

Material: Multiple organ resection + right breast

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis: Cancer of the right breast.

HIFAA Discrepancy		X

Examination performed on:

Macroscopic description:

Right breast sized 19.0 x 14.0 x 2.5 cm removed without axillary tissues and with a skin flap of 14 x 8 cm. Tumour sized 1.1 x 0.6 x 1.0 cm found in upper inner quadrant, located 2.5 cm from the lower boundary, 0.5 cm from the base and 1.0 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum NHG1 (2 + 2 + 1/5 mitoses/10 HPF - visual area 0.55 mm).

Numerous foci of carcinoma ductale in situ (DCIS) found within the tumour (cribrate type with medium nuclear atypia and point necrosis, 30% of the tumour).

Mamilla sine laesionibus.

Glandular texture showing lesions of the type mastopathia fibrosa et cystica.

Invasive lesions are situated 5 cm from the base.

Histopathological diagnosis:

Carcinoma ductale invasivum et in situ mammae dextrae. Invasive and in situ ductal carcinoma of the right breast. (NHG1, pT1c, pNx).

Compliance validated by: dr

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei. HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody. Negative reaction in invasive cancerous cells (Score=1+).

dr

dr

Source: NCI Genomic Data Commons file 8e26c786-e144-4ce2-9792-fe957cd03aa8 (TCGA-D8-A27L.1281F503-C256-4DFF-A3BD-BD5E51CE4249.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).